Somatic mutation profile of tumor specimen TARGET-30-PATXHW-01A (aliquot TARGET-30-PATXHW-01A-01D) from TARGET case TARGET-30-PATXHW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.5 years (927 days).
Specimen TARGET-30-PATXHW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e01d9d2-5fcf-4092-8a67-5a3f7a095c5b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXHW-10A (Blood Derived Normal), aliquot TARGET-30-PATXHW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/516d1773-b737-4fce-a40a-eaa415ff3e36

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK8 | c.1477del p.R493Dfs*16 | Frame Shift Del (DEL) | VAF 58/165 reads (35%) | called by mutect2, pindel, varscan2
- ARID1B | c.3096+875C>T | Intron (SNP) | VAF 19/75 reads (25%) | catalogued as COSV51659239; called by muse, mutect2, varscan2
- GAREM1 | c.*2613dup | 3'UTR (INS) | VAF 42/118 reads (36%) | catalogued as rs1202599439; called by mutect2, varscan2
